Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVP, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVP-01A (Primary Tumor).

ICD-O-3

Carcinoma, hepatocellular NOS
8170/3

Site: Liver C22.0

7/24/23/14

DIAGNOSIS:

Liver, extended left hemihepatectomy:

Hepatocellular carcinoma, caudate lobe

- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 5.0x4.0x3.4cm
- 3) Gross type: nodular with perinodal extension
- 4) Satellite nodule: absent
- 5) Histologic type: microtrabecular
- 6) Cell type: cirrhotomimetic
- 7) Edmondson and Steiner's histologic grade:
- The worst differentiation: 2
- The major differentiation: 1
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: absent
- 10) Tumor necrosis: present (30%)
- 11) Vascular invasion(microscopic): absent
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: absent
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: negative (safety margin: 0.5cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT1), (pT2)
- 23) Related biopsy:
- 24) Additional pathologic findings
- a) Chronic hepatitis: none
- b) Cirrhosis: present, active
- c) Dysplasia: absent

Gallbladder, cholecystectomy:

No diagnostic abnormalities recognized

Source: NCI Genomic Data Commons file 07fe4f0f-7acd-4cd1-afb4-d1ebbc217f0c (TCGA-DD-AAVP.E930F87E-767F-4413-909E-97F7ABAD3D51.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).